TCGA case TCGA-OR-A5JC — Adrenocortical Carcinoma (TCGA-ACC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bdfcd747-f6a2-42e2-bc9b-483112205fa8

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Australia; Age at index: 37 years; Vital status: Dead; Days to death: 1,750 days (4.8 years).

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; ICD-10 code: C74.0; Tissue or organ of origin: Cortex of adrenal gland; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 38.0 years (13,862 days); Year of diagnosis: 2001; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Weiss assessment findings: Atypical Mitotic Figures / Cytoplasm presence <= to 25% / Diffuse Architecture / Mitotic Rate > 5/50 HPF / Necrosis / Nuclear Grade III or IV / Sinusoid Invasion / Venous Invasion; Weiss assessment score: 8.
   Pathology details: Consistent pathology review: Yes.
   Recorded, whether given is unknown: Chemotherapy (Mitotane).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,750.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 24.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factor method of diagnosis: Biochemical Assessment; Risk factors: Estrogen Excess.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-OR-A5JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 30 mg.
  Slide TCGA-OR-A5JC-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 9; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-OR-A5JC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-OR-A5JC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No.
- Primary pathology: Submitted tumor site: Adrenal; Histologic diagnosis: Adrenocortical carcinoma- Usual Type; Lymph nodes examined: No; Mitoses per 50 hpf: 24.
- Primary pathology, Weiss assessment report, Weiss assessment categories: Nuclear grade III IV: Nuclear Grade III or IV Present; Mitotic rate: Mitotic Rate > 5/50 HPF Present; Atypical mitotic figures: Atypical Mitotic Figures Present; Cytoplasm presence less than equal 25 percent: Cytoplasm presence <= 25% Present; Diffuse architecture: Diffuse Architecture Present; Necrosis: Necrosis Present; Weiss venous invasion: Venous Invasion Present; Sinusoid invasion: Sinusoid Invasion Present; Invasion of tumor capsule: Invasion of Tumor Capsule Absent.
- Primary pathology, Excess adrenal hormone history types: History adrenal hormone excess: Estrogen.
- Primary pathology, Germline genotype testing report: Molecular studies others performed: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,750 days; disease-specific survival: event status not recorded, 1,750 days; progression-free interval: no event (censored), 1,750 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-OR-A5JC-01A-11D-A29H-01): tumor purity 0.75, ploidy 2.77, whole-genome doublings 1.
